Somatic mutation profile of tumor specimen MMRF_2742_1_BM_CD138pos (aliquot MMRF_2742_1_BM_CD138pos_T1_KHS5U_L14892) from MMRF case MMRF_2742, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,755 days).
Specimen MMRF_2742_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50b5adfe-cb93-4788-984b-91e968daba23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2742_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2742_1_PB_WBC_C3_KHS5U_L14894; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9db6fb9-bbf3-452f-af8e-a9cbdcff03c8

The open-access MAF lists 148 somatic variants for this specimen: 72 protein-altering or splice-affecting, 17 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 32, Silent 17, Intron 12, 5'UTR 8, 3'Flank 5, Splice Region 4, Splice Site 3, Nonsense Mutation 2, 5'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1910T>A p.L637Q (on ENST00000288602 / NM_001374244.1; = p.L597Q on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs121913366, COSV56072463, COSV56121113, COSV56136756; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs147171162; called by muse, mutect2, varscan2
- ACO1 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as rs202070059, COSV59383722, COSV59385241; called by muse, mutect2, varscan2
- ANO6 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1271693493; called by muse, mutect2, varscan2
- BCAS3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs753613820, COSV66770082; called by muse, mutect2, varscan2
- BCL7A | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1163751698; called by muse, varscan2
- CARMIL1 | c.3109A>C p.M1037L | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61517239; called by muse, mutect2, varscan2
- CDCA2 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.027); catalogued as COSV57947403; called by muse, mutect2, varscan2
- CDH4 | c.2746G>C p.D916H | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100848638; called by muse, mutect2, varscan2
- CHD9 | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV68298472; called by muse, mutect2, varscan2
- CORO2B | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.081); catalogued as rs1351079320; called by muse, mutect2
- HEATR1 | c.4168G>A p.V1390I | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as rs750396656, COSV63980805; called by muse, mutect2, varscan2
- HNRNPM | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1458964760; called by muse, mutect2, varscan2
- IGF2R | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs199514599; called by muse, mutect2, varscan2
- IGHV1-69 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 127/293 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs369593040; called by muse, mutect2
- IGKV4-1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs368562334; called by muse, varscan2
- IGKV4-1 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs541963022; called by muse, varscan2
- IGKV4-1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.435); catalogued as rs560608508; called by muse, varscan2
- IGKV4-1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs370732594; called by muse, varscan2
- IGLV3-1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 251/387 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs185803370; called by muse, varscan2
- IRF2BP2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1214621282; called by muse, mutect2, varscan2
- KIF3B | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65228270, COSV65229103; called by muse, mutect2, varscan2
- MAT1A | c.1161G>A p.W387* | Nonsense Mutation (SNP) | VAF 58/170 reads (34%) | catalogued as CM023811; called by muse, mutect2
- MCF2L | c.2756G>A p.R919H (on ENST00000375608; = p.R887H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56175387, COSV99996173; called by muse, mutect2, varscan2
- MFSD2A | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757547777; called by muse, mutect2, varscan2
- MPO | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs1476706511, COSV99832859; called by muse, mutect2, varscan2
- MYO18B | c.5989C>T p.R1997W | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765093050, COSV59126672; called by muse, mutect2, varscan2
- NEUROD6 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 55/415 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51770924; called by muse, mutect2, varscan2
- PLCE1 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as rs1482772158, COSV53357049; called by muse, mutect2, varscan2
- PRPF40B | c.1994A>G p.Q665R (on ENST00000380281; = p.Q652R on NM_012272.3) | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.474); catalogued as COSV53298204; called by muse, mutect2, varscan2
- SLC22A12 | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 122/340 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as rs1014455077; called by muse, mutect2, varscan2
- TMCO5A | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT tolerated (0.59); PolyPhen benign (0.026); catalogued as rs201144596, COSV60465261; called by muse, mutect2, varscan2
- TTN | c.93176-5dup | Splice Region (INS) | VAF 56/142 reads (39%) | catalogued as rs775413714; called by mutect2, varscan2
- ADAMTSL2 | c.2791A>T p.N931Y | Missense Mutation (SNP) | VAF 283/472 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ATR | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 146/470 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL7A | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, varscan2
- BET1 | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 42/130 reads (32%) | called by muse, varscan2
- C1GALT1C1L | c.506A>C p.H169P | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CHD9 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CORO2A | c.455_460del p.G152_Y153del | In Frame Del (DEL) | VAF 58/277 reads (21%) | called by mutect2, pindel, varscan2
- CSPP1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CTR9 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CXCR2 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CYP2W1 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DARS2 | c.1563+3A>C | Splice Region (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- FABP7 | c.44A>C p.Q15P | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FAM221A | c.743A>T p.D248V | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.035); called by muse, mutect2
- FOLR3 | c.358-1G>A p.X120_splice | Splice Site (SNP) | VAF 102/232 reads (44%) | called by muse, mutect2, varscan2
- HUWE1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ICOS | c.308A>T p.H103L | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- IGHV2-70D | c.228T>A p.D76E | Missense Mutation (SNP) | VAF 66/90 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, varscan2
- IGHV2-70D | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, varscan2
- IGHV2-70D | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 73/96 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, varscan2
- IGHV2-70D | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 36/46 reads (78%) | called by muse, varscan2
- IL27RA | c.1082C>G p.P361R | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KCNT2 | c.1937T>C p.L646P | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- LRRIQ3 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGST1 | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- NOS1AP | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11A1 | c.920G>A p.C307Y | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6F1 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PABPN1 | c.22_44del p.A8Rfs*38 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel
- PIEZO2 | c.5546C>A p.A1849E | Missense Mutation (SNP) | VAF 215/343 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTAR1 | c.642+3A>C | Splice Region (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- PTCHD4 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- REM2 | c.61T>A p.S21T | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RINT1 | c.996+1_996+14del p.X332_splice | Splice Site (DEL) | VAF 32/214 reads (15%) | called by pindel, varscan2
- RPE65 | c.1186T>C p.C396R | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCAF4 | c.2189A>C p.N730T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM253 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.104); called by muse, mutect2
- WDR48 | c.48+5G>T | Splice Region (SNP) | VAF 96/324 reads (30%) | called by muse, mutect2, varscan2
- ZNF676 | c.1840A>C p.I614L (on ENST00000650058; = p.I582L on NM_001001411.3) | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CDH17 | c.1077C>A p.I359= | Silent (SNP) | VAF 16/89 reads (18%) | called by muse, varscan2
- COMMD5 | c.622C>T p.L208= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- DLAT | c.195T>G p.S65= | Silent (SNP) | VAF 30/283 reads (11%) | called by muse, mutect2
- HBS1L | c.618C>T p.S206= | Silent (SNP) | VAF 88/277 reads (32%) | catalogued as rs1028917677; called by muse, mutect2, varscan2
- IGHV2-70D | c.306A>C p.T102= | Silent (SNP) | VAF 46/69 reads (67%) | called by muse, varscan2
- MDN1 | c.16764G>A p.E5588= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- MUC4 | c.15762C>T p.A5254= (on ENST00000463781 / NM_018406.7; = p.A1018= on NM_004532.6) | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as rs774153313; called by muse, mutect2, varscan2
- NUP62 | c.1335G>A p.K445= | Silent (SNP) | VAF 117/364 reads (32%) | called by muse, mutect2, varscan2
- PAX3 | c.1434T>G p.T478= | Silent (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- PIK3CD | c.732C>T p.N244= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs751020278, COSV63131812; called by muse, mutect2, varscan2
- RLN2 | c.240T>C p.D80= (on ENST00000381627 / NM_134441.3; = p.I65T on NM_005059.3) | Silent (SNP) | VAF 224/361 reads (62%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.777C>T p.P259= | Silent (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- SSTR1 | c.762C>A p.A254= | Silent (SNP) | VAF 79/199 reads (40%) | called by muse, mutect2, varscan2
- STAB2 | c.3219T>C p.D1073= | Silent (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- STXBP1 | c.969C>T p.T323= | Silent (SNP) | VAF 55/159 reads (35%) | called by muse, mutect2, varscan2
- TCTN3 | c.390C>T p.S130= | Silent (SNP) | VAF 97/225 reads (43%) | catalogued as rs533262975; called by muse, mutect2, varscan2
- TMEM253 | c.619C>A p.R207= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2, varscan2
- ANKRD12 | c.*528A>G | 3'UTR (SNP) | VAF 106/157 reads (68%) | called by muse, mutect2, varscan2
- AP4E1 | c.*1883G>A | 3'UTR (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP11B | c.-173G>T | 5'UTR (SNP) | VAF 52/181 reads (29%) | called by muse, mutect2, varscan2
- BEST3 | c.482-4988del | Intron (DEL) | VAF 34/82 reads (41%) | called by mutect2, pindel, varscan2
- CACNA1E | c.*5089C>A | 3'UTR (SNP) | VAF 57/112 reads (51%) | called by muse, mutect2, varscan2
- CALCRL | c.*2359A>G | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- CERS3 | c.*1635C>T | 3'UTR (SNP) | VAF 46/88 reads (52%) | catalogued as rs776576323; called by muse, mutect2, varscan2
- CHRM2 | chr7:137018270 A>C | 3'Flank (SNP) | VAF 91/159 reads (57%) | called by muse, mutect2, varscan2
- DBNL | c.*4791C>G | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- DEXI | c.-335A>C | 5'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- DIS3 | c.*418T>C | 3'UTR (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- EIF1AX | c.*2784C>T | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- ESRRG | c.*418_*419insC | 3'UTR (INS) | VAF 43/102 reads (42%) | called by mutect2, pindel, varscan2
- FAM189A1 | c.*1303G>T | 3'UTR (SNP) | VAF 52/163 reads (32%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161898057 A>G | 3'Flank (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- GPR27 | c.*934G>A | 3'UTR (SNP) | VAF 7/55 reads (13%) | catalogued as rs1029701828; called by muse, mutect2, varscan2
- HADH | c.-17G>C | 5'UTR (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- HNRNPLP2 | n.1521C>T | RNA (SNP) | VAF 27/288 reads (9%) | called by muse, mutect2, varscan2
- KCNMA1 | c.*1411T>G | 3'UTR (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- KCTD9 | c.-184G>A | 5'UTR (SNP) | VAF 69/210 reads (33%) | called by muse, mutect2, varscan2
- KLHL4 | c.*378G>T | 3'UTR (SNP) | VAF 30/30 reads (100%) | called by muse, varscan2
- LANCL1 | chr2:210433940 T>C | 3'Flank (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- LATS1 | c.-59A>G | 5'UTR (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- LEPR | c.*2801G>T | 3'UTR (SNP) | VAF 55/134 reads (41%) | called by muse, mutect2, varscan2
- LTB | c.163-29C>G | Intron (SNP) | VAF 350/587 reads (60%) | catalogued as rs532552573, COSV53001171; called by muse, varscan2
- LTB | c.163-142T>C | Intron (SNP) | VAF 212/338 reads (63%) | called by muse, varscan2
- LTB | c.162+188C>G | Intron (SNP) | VAF 68/100 reads (68%) | called by muse, varscan2
- LZTS1 | c.*1878C>T | 3'UTR (SNP) | VAF 6/120 reads (5%) | catalogued as rs1021062597; called by muse, mutect2
- MIGA1 | c.*2495G>A | 3'UTR (SNP) | VAF 66/117 reads (56%) | called by muse, mutect2, varscan2
- MMEL1 | c.2163+93G>A | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- MMP15 | c.*705C>A | 3'UTR (SNP) | VAF 57/141 reads (40%) | called by muse, mutect2, varscan2
- MS4A3 | c.-15-25G>A | Intron (SNP) | VAF 134/488 reads (27%) | called by muse, mutect2, varscan2
- MTAP | c.813+2770A>G | Intron (SNP) | VAF 84/255 reads (33%) | catalogued as rs111350457; called by muse, mutect2, varscan2
- MYADM | chr19:53875950 C>T | 3'Flank (SNP) | VAF 33/84 reads (39%) | catalogued as rs1212322210; called by muse, mutect2, varscan2
- OSBPL10 | c.2251-803del | Intron (DEL) | VAF 72/237 reads (30%) | called by mutect2, pindel, varscan2
- PDE6H | c.*116C>G | 3'UTR (SNP) | VAF 49/240 reads (20%) | called by muse, mutect2, varscan2
- PLCZ1 | c.12-387T>G | Intron (SNP) | VAF 91/266 reads (34%) | called by muse, mutect2, varscan2
- PPM1E | c.*1870G>T | 3'UTR (SNP) | VAF 67/165 reads (41%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82978150 A>C | 3'Flank (SNP) | VAF 91/145 reads (63%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.*575G>A | 3'UTR (SNP) | VAF 44/120 reads (37%) | called by muse, mutect2, varscan2
- RALGPS1 | c.910+9495G>A | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as rs1428865263; called by muse, mutect2
- RBP2 | chr3:139452880 del CATATAAA | 3'UTR (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- RCBTB1 | c.*1041T>A | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- RNF125 | c.*1079T>C | 3'UTR (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- SAV1 | c.*1019T>G | 3'UTR (SNP) | VAF 166/420 reads (40%) | called by muse, mutect2, varscan2
- SCARA5 | c.*569G>A | 3'UTR (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- SCRN3 | c.*1247C>T | 3'UTR (SNP) | VAF 43/87 reads (49%) | catalogued as rs1252773318; called by muse, mutect2, varscan2
- SDK1 | c.*1172del | 3'UTR (DEL) | VAF 36/170 reads (21%) | called by mutect2, pindel, varscan2
- SH2B3 | c.*2207_*2211del | 3'UTR (DEL) | VAF 31/158 reads (20%) | called by mutect2, pindel, varscan2
- SIX5 | c.-54G>C | 5'UTR (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1211-1773C>A | Intron (SNP) | VAF 19/229 reads (8%) | called by muse, mutect2
- SLC25A53 | c.*16C>T | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- SYNPO2 | c.*3147A>G | 3'UTR (SNP) | VAF 57/120 reads (48%) | called by muse, mutect2, varscan2
- TPRA1 | c.-818T>C | 5'UTR (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- UNC13C | c.5457+540T>C | Intron (SNP) | VAF 143/423 reads (34%) | called by muse, mutect2, varscan2
- WWC2 | chr4:183098253 C>A | 5'Flank (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*4206A>T | 3'UTR (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- ZNF155 | c.-25C>T | 5'UTR (SNP) | VAF 87/430 reads (20%) | called by muse, mutect2, varscan2
- ZNF33B | c.*1868G>A | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
